Somatic mutation profile of tumor specimen ALCH-B1U3-TTP1-A (aliquot ALCH-B1U3-TTP1-A-1-0-D-A76B-36) from ALCHEMIST case ALCH-B1U3, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 63.8 years (23,315 days).
Specimen ALCH-B1U3-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f349c8df-6889-49db-8fa2-c8002fef8da3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B1U3-NB1-A (Blood Derived Normal), aliquot ALCH-B1U3-NB1-A-1-0-D-A76B-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2c5c0a0a-638a-4354-9d58-0827cc9cad0c

The open-access MAF lists 42 somatic variants for this specimen: 33 protein-altering or splice-affecting, 7 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 27, Silent 7, Nonsense Mutation 5, 5'Flank 1, RNA 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC2 | c.1893C>A p.C631* | Nonsense Mutation (SNP) | VAF 32/498 reads (6%) | catalogued as rs1257076487; ClinVar: pathogenic; called by muse, mutect2
- ABCF1 | c.26C>T p.P9L | Missense Mutation (SNP) | VAF 16/324 reads (5%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as rs767397757, COSV58228252; called by muse, mutect2
- CADPS | c.1895C>T p.P632L | Missense Mutation (SNP) | VAF 16/266 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs776683516; called by muse, mutect2
- CD1E | c.845G>T p.G282V | Missense Mutation (SNP) | VAF 8/83 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1305276290; called by muse, mutect2
- EGFLAM | c.1464C>A p.N488K | Missense Mutation (SNP) | VAF 19/185 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.627); catalogued as rs1178776107; called by muse, mutect2, varscan2
- EPPK1 | c.5188G>A p.D1730N | Missense Mutation (SNP) | VAF 71/290 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs782004743, COSV73262271; called by muse, mutect2, varscan2
- GALR3 | c.251C>T p.T84M | Missense Mutation (SNP) | VAF 18/200 reads (9%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.995); catalogued as rs142109402, COSV99967992; called by muse, mutect2
- GLI1 | c.2678T>C p.L893P | Missense Mutation (SNP) | VAF 10/162 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.577); catalogued as rs747845466; called by muse, mutect2
- HTRA2 | c.1057G>A p.G353R | Missense Mutation (SNP) | VAF 30/386 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.548); catalogued as rs755545814, COSV51206423; called by muse, mutect2
- NLRP3 | c.1643G>T p.R548L | Missense Mutation (SNP) | VAF 52/703 reads (7%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as COSV60220327; called by muse, mutect2
- PCDHA6 | c.1438C>T p.R480* | Nonsense Mutation (SNP) | VAF 64/614 reads (10%) | catalogued as rs781954491, COSV65345484, COSV65346300; called by muse, mutect2
- PTPRT | c.2996G>A p.R999Q | Missense Mutation (SNP) | VAF 12/224 reads (5%) | SIFT tolerated (0.2); PolyPhen benign (0.096); catalogued as rs868489194, COSV61963246; called by muse, mutect2
- TIAM2 | c.2563C>T p.R855* | Nonsense Mutation (SNP) | VAF 17/204 reads (8%) | catalogued as rs370100446, COSV59697191; called by muse, mutect2
- YIPF6 | c.175C>T p.R59C | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.586); catalogued as rs776029090, COSV65855242; called by muse, mutect2, varscan2
- ZNF696 | c.898C>T p.R300C | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs1002330844; called by muse, mutect2, varscan2
- ACACA | c.2180C>T p.P727L | Missense Mutation (SNP) | VAF 50/316 reads (16%) | SIFT tolerated (0.66); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- ARFIP2 | c.932G>A p.G311E | Missense Mutation (SNP) | VAF 14/305 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- BCAT1 | c.649G>T p.G217* | Nonsense Mutation (SNP) | VAF 8/88 reads (9%) | called by muse, mutect2
- CACNA1D | c.6262A>T p.I2088F (on ENST00000350061 / NM_001128840.3; = p.I2108F on NM_000720.4) | Missense Mutation (SNP) | VAF 18/181 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.797); called by muse, mutect2
- ERVW-1 | c.407T>C p.L136P | Missense Mutation (SNP) | VAF 34/608 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.831); called by muse, mutect2
- FNIP1 | c.2678A>C p.Q893P | Missense Mutation (SNP) | VAF 27/375 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0.003); called by muse, mutect2
- HNRNPUL1 | c.74T>C p.L25P | Missense Mutation (SNP) | VAF 15/140 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.01); called by muse, mutect2
- ITPKB | c.415C>T p.Q139* | Nonsense Mutation (SNP) | VAF 34/333 reads (10%) | called by muse, mutect2
- MAPT | c.1702C>T p.P568S (on ENST00000262410 / NM_001377265.1; = p.P176S on NM_005910.5) | Missense Mutation (SNP) | VAF 34/358 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.237); called by muse, mutect2
- MYO7B | c.4736T>A p.L1579H | Missense Mutation (SNP) | VAF 14/168 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- NCAM2 | c.2018G>A p.G673E | Missense Mutation (SNP) | VAF 10/182 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PRKCQ | c.1782C>G p.D594E | Missense Mutation (SNP) | VAF 18/117 reads (15%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- QTRT1 | c.919G>C p.E307Q | Missense Mutation (SNP) | VAF 13/245 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.003); called by muse, mutect2
- SLC18B1 | c.637A>G p.M213V | Missense Mutation (SNP) | VAF 15/141 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TOX | c.579G>C p.L193F | Missense Mutation (SNP) | VAF 26/621 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.973); called by muse, mutect2
- WDR70 | c.1558A>C p.K520Q | Missense Mutation (SNP) | VAF 24/482 reads (5%) | SIFT tolerated (0.16); PolyPhen benign (0.039); called by muse, mutect2
- XYLT2 | c.1555G>T p.D519Y | Missense Mutation (SNP) | VAF 45/274 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ZBED4 | c.3284_3290del p.E1095Afs*10 | Frame Shift Del (DEL) | VAF 10/71 reads (14%) | called by mutect2, pindel, varscan2
- AHNAK | c.16350G>A p.P5450= | Silent (SNP) | VAF 20/290 reads (7%) | catalogued as rs146447446; called by muse, mutect2
- CHST6 | c.243G>T p.S81= | Silent (SNP) | VAF 14/162 reads (9%) | catalogued as rs561468086; called by muse, mutect2
- DLGAP2 | c.1467C>T p.S489= | Silent (SNP) | VAF 24/212 reads (11%) | catalogued as rs201567259; called by muse, mutect2, varscan2
- LPA | c.5439G>A p.P1813= | Silent (SNP) | VAF 46/375 reads (12%) | catalogued as rs747134808; called by muse, mutect2, varscan2
- OR10A2 | c.456T>C p.S152= | Silent (SNP) | VAF 36/406 reads (9%) | called by muse, mutect2
- PSG8 | c.1137C>A p.L379= | Silent (SNP) | VAF 52/578 reads (9%) | catalogued as rs749649602; called by muse, mutect2
- ZNF90 | c.1302C>T p.F434= | Silent (SNP) | VAF 14/342 reads (4%) | called by muse, mutect2
- BSG | chr19:571572 C>T | 5'Flank (SNP) | VAF 24/301 reads (8%) | catalogued as rs1210560331; called by muse, mutect2
- KIR3DX1 | n.1172C>T | RNA (SNP) | VAF 13/328 reads (4%) | catalogued as rs117732069, COSV55601959; called by muse, mutect2
